Somatic mutation profile of tumor specimen TCGA-59-2350-01A (aliquot TCGA-59-2350-01A-01W-0799-08) from TCGA case TCGA-59-2350, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3.
Specimen TCGA-59-2350-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba1c938b-8abc-40bf-a3ac-f9c838f680fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2350-11A (Solid Tissue Normal), aliquot TCGA-59-2350-11A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd870f0a-20f0-4e06-9fcf-284b1e088c66

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Frame Shift Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 77/102 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF12 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1457850226, COSV63107908; called by muse, mutect2, varscan2
- CTSL | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58247874; called by muse, mutect2, varscan2
- CYP4F12 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 187/617 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as rs200246876; called by muse, mutect2, varscan2
- DST | c.16390G>C p.E5464Q (on ENST00000361203 / NM_001374722.1; = p.E3052Q on NM_015548.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); catalogued as COSV55045738; called by muse, mutect2, varscan2
- FAM219A | c.492dup p.K165Qfs*39 (on ENST00000445726; = p.K148Qfs*39 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs760074479; called by mutect2, varscan2
- GEMIN4 | c.700G>T p.G234W | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV56747924; called by muse, mutect2, varscan2
- KLF11 | c.189A>T p.K63N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV59941830; called by muse, mutect2
- LIG4 | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV63598288; called by muse, mutect2, varscan2
- MICAL2 | c.3962G>T p.S1321I | Missense Mutation (SNP) | VAF 228/310 reads (74%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.391); catalogued as COSV56289213; called by muse, mutect2, varscan2
- MYF5 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57357005; called by muse, mutect2, varscan2
- OR8K3 | c.860T>G p.L287W | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.228); catalogued as COSV57130882, COSV57132564, COSV57133424; called by muse, mutect2, varscan2
- OTOL1 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.044); catalogued as rs563420853, COSV60008769; called by muse, mutect2, varscan2
- PLXNA2 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995889959, COSV65445778; called by muse, varscan2
- POLK | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs752857230, COSV104385564, COSV54040677; called by muse, mutect2, varscan2
- PTPRG | c.1284del p.N429Tfs*26 | Frame Shift Del (DEL) | VAF 86/250 reads (34%) | catalogued as COSV55643922; called by mutect2, pindel, varscan2
- REEP5 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); catalogued as rs1354464761, COSV54845173; called by muse, mutect2, varscan2
- SLC27A1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.928); catalogued as rs750726250, COSV99393269; called by muse, mutect2, varscan2
- SPDYE5 | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs782751740, COSV71596511; called by muse, varscan2
- SPRR3 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 152/363 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV54880914, COSV54881787; called by muse, mutect2, varscan2
- TUT7 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV52899505; called by muse, mutect2, varscan2
- USH2A | c.5266G>A p.V1756I | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs143208990; called by muse, mutect2, varscan2
- RERGL | c.277del p.A93Lfs*6 | Frame Shift Del (DEL) | VAF 129/630 reads (20%) | called by pindel, varscan2
- TRAV8-2 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 311/707 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- EDRF1 | c.1560A>G p.E520= (on ENST00000356792 / NM_001202438.2; = p.E486= on NM_015608.2) | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as COSV61766628; called by muse, mutect2, varscan2
- EEPD1 | c.702G>T p.P234= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs776101800, COSV54203970; called by muse, mutect2, varscan2
- ME3 | c.1659C>T p.L553= | Silent (SNP) | VAF 108/246 reads (44%) | catalogued as rs769718958, COSV62775617; called by muse, mutect2, varscan2
- POLR1A | c.4995C>T p.N1665= | Silent (SNP) | VAF 96/276 reads (35%) | catalogued as COSV55700746; called by muse, mutect2, varscan2
- PSG1 | c.675C>A p.A225= | Silent (SNP) | VAF 738/1825 reads (40%) | catalogued as COSV54958826; called by muse, mutect2, varscan2
- RAB6C | c.606C>T p.S202= | Silent (SNP) | VAF 119/324 reads (37%) | catalogued as COSV101308492; called by muse, mutect2, varscan2
- TGFBI | c.1152A>C p.A384= | Silent (SNP) | VAF 93/225 reads (41%) | catalogued as COSV59354943; called by muse, mutect2, varscan2
- TGIF2LX | c.177C>T p.A59= | Silent (SNP) | VAF 79/94 reads (84%) | catalogued as COSV99383299, COSV99383406; called by muse, mutect2, varscan2
- TTN | c.10360+1134C>T | Intron (SNP) | VAF 183/424 reads (43%) | catalogued as rs727505183, COSV100610500; ClinVar: likely benign; called by muse, mutect2, varscan2
